Somatic mutation profile of tumor specimen TCGA-C5-A2M2-01A (aliquot TCGA-C5-A2M2-01A-21D-A18J-09) from TCGA case TCGA-C5-A2M2, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2; Age at diagnosis: 56.1 years (20,480 days).
Specimen TCGA-C5-A2M2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab67260a-b824-4044-81a3-1bd0860970d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A2M2-10A (Blood Derived Normal), aliquot TCGA-C5-A2M2-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/182e7f13-42b2-4923-adbf-5e2587539246

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 11, Nonsense Mutation 4, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 94/125 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC10 | c.2959G>T p.V987L (on ENST00000372530 / NM_001198934.2; = p.V959L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV55084718; called by muse, mutect2, varscan2
- ABHD4 | c.658C>T p.R220* | Nonsense Mutation (SNP) | VAF 16/33 reads (48%) | catalogued as rs200393007, COSV99360651; called by muse, mutect2, varscan2
- ANKRD33 | c.371G>A p.R124Q (on ENST00000340970 / NM_001304459.2; = p.R249Q on NM_182608.4) | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); catalogued as rs147364846; called by muse, mutect2, varscan2
- ANKRD34B | c.1421C>A p.S474Y | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV100103678; called by muse, mutect2
- ATAD3C | c.1094C>T p.T365M | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0.028); catalogued as rs190504905; called by muse, mutect2, varscan2
- ATG2B | c.227C>A p.S76* | Nonsense Mutation (SNP) | VAF 3/25 reads (12%) | catalogued as COSV63421814; called by muse, mutect2
- BRMS1 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs756789967, COSV60925486; called by muse, mutect2, varscan2
- CDC42BPB | c.4455C>A p.D1485E | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV63473954; called by muse, mutect2, varscan2
- CELSR1 | c.5897G>A p.C1966Y | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53084081; called by muse, mutect2, varscan2
- CYP27B1 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV56983896; called by muse, mutect2, varscan2
- DIP2B | c.2813G>T p.C938F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99999651; called by muse, mutect2
- EGFR | c.3289G>A p.V1097I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs775345513, COSV51773844; called by mutect2, varscan2
- ERBB3 | c.2849T>C p.I950T | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs540444132, COSV57247420; called by muse, mutect2, varscan2
- FANCM | c.1264C>T p.R422C | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs150574630; called by muse, mutect2, varscan2
- FLCN | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs138070947; ClinVar: conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- FLT4 | c.118G>A p.V40I | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs770143594, COSV56099123, COSV56114677, COSV56122798; called by muse, mutect2, varscan2
- FOLH1 | c.286A>T p.I96F | Missense Mutation (SNP) | VAF 38/70 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV57045972; called by muse, mutect2, varscan2
- GALNT11 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs375106713; called by muse, mutect2, varscan2
- GFRA3 | c.791G>A p.R264H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1405304751, COSV51227957; called by muse, mutect2, varscan2
- HDAC6 | c.2984C>T p.S995L | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (0.27); PolyPhen benign (0.144); catalogued as rs375164434, COSV61927594; called by muse, mutect2, varscan2
- HSD17B6 | c.154C>T p.R52* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as rs377658371; called by mutect2, varscan2
- ITGB4 | c.4796G>A p.R1599H | Missense Mutation (SNP) | VAF 26/28 reads (93%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs770427712, COSV52322117; called by muse, mutect2, varscan2
- KCNA1 | c.38C>T p.S13L | Missense Mutation (SNP) | VAF 11/14 reads (79%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs1253210703, COSV66836612; called by muse, mutect2, varscan2
- MARK1 | c.2015G>T p.G672V | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100857604; called by muse, mutect2
- MICALL2 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.086); catalogued as rs760862909, COSV52514194; called by muse, mutect2, varscan2
- MMP26 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as COSV56171388; called by muse, mutect2, varscan2
- MYO16 | c.3974C>T p.A1325V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1460924180, COSV62745786; called by muse, mutect2
- NCL | c.1223A>G p.E408G | Missense Mutation (SNP) | VAF 29/33 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.886); catalogued as rs779768501, COSV59544919; called by muse, mutect2, varscan2
- PCDHA6 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs1481552888, COSV65342059; called by muse, mutect2, varscan2
- PRUNE2 | c.2789G>A p.G930E | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.357); catalogued as COSV65038100; called by muse, mutect2, varscan2
- SLC25A5 | c.858T>G p.F286L | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58625155; called by muse, mutect2, varscan2
- SNX1 | c.1306C>T p.R436W | Missense Mutation (SNP) | VAF 30/52 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV56037494; called by muse, mutect2, varscan2
- SPG7 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV99245545; called by muse, mutect2, varscan2
- SPIRE1 | c.1561C>T p.R521* (on ENST00000409402 / NM_001128626.2; = p.R507* on NM_020148.3) | Nonsense Mutation (SNP) | VAF 43/82 reads (52%) | catalogued as rs747265516, COSV59152682; called by muse, mutect2, varscan2
- TANGO6 | c.3046C>T p.R1016C | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1205062277, COSV55760760; called by muse, mutect2, varscan2
- TIMM23 | c.82C>T p.H28Y | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.139); catalogued as rs1554912001; called by muse, mutect2, varscan2
- TNFAIP3 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as rs775850329, COSV52796768, COSV52798177; called by muse, mutect2, varscan2
- TRIM9 | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as COSV53613038; called by muse, mutect2, varscan2
- VSIG1 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.059); catalogued as COSV54257743; called by muse, mutect2, varscan2
- VSIG4 | c.1001T>G p.M334R | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated (0.44); PolyPhen benign (0.094); catalogued as COSV66073230; called by muse, mutect2, varscan2
- WNT2B | c.247C>T p.R83W (on ENST00000369684 / NM_024494.3; = p.R64W on NM_004185.4) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759333195, COSV56672626; called by muse, mutect2, varscan2
- XIAP | c.1181A>T p.E394V | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100849012; called by muse, mutect2
- ZNF468 | c.1359C>A p.H453Q | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV54693391; called by muse, mutect2, varscan2
- BCL2L11 | c.479del p.N160Tfs*10 (on ENST00000393256 / NM_138621.5; = p.N100Tfs*10 on NM_006538.5) | Frame Shift Del (DEL) | VAF 23/49 reads (47%) | called by mutect2, pindel, varscan2
- IGLV5-37 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TCOF1 | c.1120del p.A374Pfs*119 (on ENST00000377797 / NM_001135243.1; = p.A297Pfs*119 on NM_000356.4) | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- ZBED4 | c.2176G>T p.G726C | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCA2 | c.1941G>A p.S647= (on ENST00000614293; = p.S617= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs374748346; called by muse, mutect2, varscan2
- ABCC9 | c.1251C>T p.V417= | Silent (SNP) | VAF 17/32 reads (53%) | catalogued as rs746029351, COSV53963420; called by muse, mutect2, varscan2
- ATCAY | c.450C>T p.N150= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as rs777047303, COSV56654402; called by muse, mutect2, varscan2
- ATXN3L | c.777C>T p.S259= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV66075266; called by muse, mutect2, varscan2
- BICDL1 | c.1383G>A p.K461= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV99985924, COSV99986005; called by muse, mutect2, varscan2
- CDC42BPG | c.411C>T p.A137= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs1374933248, COSV61345639; called by muse, mutect2, varscan2
- MDGA1 | c.2856G>A p.A952= | Silent (SNP) | VAF 10/16 reads (63%) | catalogued as rs757335830, COSV51792047; called by muse, mutect2, varscan2
- MINAR1 | c.2685G>C p.L895= | Silent (SNP) | VAF 23/40 reads (58%) | catalogued as COSV59581005, COSV59586288; called by muse, mutect2, varscan2
- PKD1 | c.6837C>T p.S2279= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs761620948, COSV51911158; called by muse, mutect2, varscan2
- SLC17A8 | c.1362C>T p.N454= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs185867962, COSV60123043; ClinVar: likely benign; called by muse, mutect2, varscan2
- ZSCAN18 | c.1458G>A p.A486= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs775951653, COSV53729926; called by muse, mutect2
- HERC2P3 | n.2037C>T | RNA (SNP) | VAF 12/40 reads (30%) | catalogued as rs1181050662; called by mutect2, varscan2
